Gene-level copy-number profile of specimen HCM-CSHL-0178-C25-85A from HCMI case HCM-CSHL-0178-C25, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G2; Age at diagnosis: 71.1 years (25,954 days).
Specimen HCM-CSHL-0178-C25-85A: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 0243777b-a49b-49b3-9cd3-a1b881be1b61.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0178-C25-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,223 have no estimate.
https://portal.gdc.cancer.gov/files/c0eea742-5c82-49a8-8675-de0aaf1cb8e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 11,216; copy number 2: 42,071; copy number 3: 4,896; copy number 4: 119; copy number 5: 12; copy number 7: 7; copy number 8: 1; copy number 9: 2; copy number 10: 19; copy number 13: 43; copy number 14: 8; copy number 15: 6.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 98 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:34,810,020–37,034,268, 86 genes, copy number 7–15 (within-gene range 4–15) (broad region; genes not listed).
- chr18:45,983,536–46,657,220, 12 genes, copy number 5: PSTPIP2, RN7SKP26, AC012569.1, RNY4P37, ATP5F1A, HAUS1, RNU6-1278P, C18orf25, RNF165, AC015959.1, AC018931.1, LOXHD1.

Autosomal genes at a single copy (total copy number 1): 11,216. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
